Somatic mutation profile of tumor specimen MMRF_1862_1_BM_CD138pos (aliquot MMRF_1862_1_BM_CD138pos_T1_KBS5U_L07237) from MMRF case MMRF_1862, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.8 years (19,645 days).
Specimen MMRF_1862_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e1684f6-24c0-446c-a294-6b223012e599.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1862_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1862_1_PB_WBC_C3_KBS5U_L07238; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e39f7fa5-c1a1-4297-87f7-b9d85bffd493

The open-access MAF lists 108 somatic variants for this specimen: 51 protein-altering or splice-affecting, 8 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 28, Intron 16, Silent 8, 3'Flank 2, RNA 2, Nonsense Mutation 2, 5'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP7 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1292292967, COSV67782581; called by muse, mutect2, varscan2
- CCDC60 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs748209413, COSV59547456; called by muse, mutect2, varscan2
- CINP | c.295T>G p.L99V | Missense Mutation (SNP) | VAF 135/247 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs546896902; called by muse, mutect2, varscan2
- COL4A2 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV64630943; called by muse, mutect2, varscan2
- CSMD1 | c.2511C>A p.F837L (on ENST00000520002; = p.F836L on NM_033225.6) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59335005; called by muse, mutect2, varscan2
- CTSL | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV58247387; called by muse, mutect2
- DNAH12 | c.8035C>T p.R2679C (on ENST00000351747; = p.R3547C on NM_001366028.2) | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs993019067, COSV61065509; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.602); catalogued as rs751192682; called by muse, mutect2, varscan2
- EML6 | c.5599G>A p.V1867I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1395720878; called by muse, varscan2
- FBF1 | c.2869C>T p.R957W (on ENST00000586717; = p.R972W on NM_001319193.1) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1021012703; called by muse, mutect2, varscan2
- GALNT18 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs372092468; called by muse, mutect2, varscan2
- IGHV4-39 | c.332G>C p.S111T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs766883330; called by muse, mutect2, varscan2
- IGLV2-14 | c.242A>T p.N81I | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs776014249; called by muse, varscan2
- IGLV3-1 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs368264723; called by muse, mutect2, varscan2
- LGR4 | c.1380G>T p.R460S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1396758062; called by muse, mutect2, varscan2
- NPAS3 | c.2098G>A p.G700R (on ENST00000356141 / NM_001164749.2; = p.G668R on NM_022123.3) | Missense Mutation (SNP) | VAF 90/155 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as rs1046166959, COSV60836001; called by muse, mutect2, varscan2
- NRP2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1312554236, COSV55929146; called by mutect2, varscan2
- PFKFB1 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | PolyPhen probably damaging (1); catalogued as rs1218319769; called by muse, mutect2, varscan2
- PLEKHM1 | c.1589A>G p.N530S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765285145; called by muse, mutect2
- POU6F2 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68884433; called by muse, mutect2, varscan2
- RASGRF2 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV54122528; called by muse, mutect2, varscan2
- RYR1 | c.7646C>T p.A2549V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757261963; called by muse, mutect2, varscan2
- TBC1D32 | c.2116T>C p.C706R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51546976; called by muse, mutect2, varscan2
- ABCC4 | c.355T>G p.Y119D | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- BRD2 | c.29+2T>A p.X10_splice | Splice Site (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- CEP170B | c.2272C>T p.R758* (on ENST00000453495; = p.R687* on NM_015005.3) | Nonsense Mutation (SNP) | VAF 75/127 reads (59%) | called by muse, mutect2, varscan2
- CFAP47 | c.8801T>A p.V2934D | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- DAAM1 | c.2829A>C p.E943D | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DEF8 | c.507T>A p.D169E (on ENST00000268676 / NM_207514.3; = p.D108E on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- GPANK1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- GUCY1A1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 153/344 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HMCN2 | c.10024G>T p.V3342L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGLV7-43 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2
- IMP4 | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- IRF3 | c.906C>G p.N302K | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IZUMO1 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.312); called by muse, varscan2
- MAP3K15 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- MIA3 | c.4643G>A p.R1548K | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OLFM1 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by mutect2, varscan2
- PAPSS2 | c.999C>A p.F333L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- PCDHGA8 | c.1115A>G p.H372R | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- POGK | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PREX1 | c.3838G>C p.E1280Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- REPIN1 | c.1448G>A p.G483D | Missense Mutation (SNP) | VAF 158/345 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF225 | c.884_891del p.A295Dfs*? | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | called by mutect2, pindel, varscan2
- SOCS3 | c.557T>G p.V186G | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SPATA31E1 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- SRSF3 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TENM1 | c.7628C>G p.A2543G | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMED3 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- TMLHE | c.968C>A p.P323Q | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRWD3 | c.4716G>A p.K1572= | Silent (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- DLG3 | c.957C>T p.D319= | Silent (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- MST1R | c.717C>A p.P239= | Silent (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- NEFL | c.990G>A p.E330= | Silent (SNP) | VAF 42/182 reads (23%) | called by muse, mutect2, varscan2
- OSBPL10 | c.2289A>G p.A763= | Silent (SNP) | VAF 77/336 reads (23%) | catalogued as rs752145076; called by muse, mutect2, varscan2
- PRAMEF12 | c.1251T>C p.S417= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- SRRM3 | c.594C>T p.P198= | Silent (SNP) | VAF 41/173 reads (24%) | called by muse, mutect2, varscan2
- TRIM3 | c.27C>T p.G9= | Silent (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- AL137060.6 | n.91A>T | RNA (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- ANXA2R | chr5:43039140 T>A | 3'Flank (SNP) | VAF 22/68 reads (32%) | called by mutect2, varscan2
- AP001496.3 | chr18:5238275 A>G | 3'Flank (SNP) | VAF 44/150 reads (29%) | called by muse, varscan2
- AP4E1 | c.*743C>G | 3'UTR (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1788C>A | Intron (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2
- CCDC141 | c.1899+1719T>G | Intron (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- CDKL5 | c.2714-5878T>C | Intron (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- DDX3X | c.*1694T>C | 3'UTR (SNP) | VAF 18/564 reads (3%) | called by muse, mutect2
- DDX41 | c.571+72C>T | Intron (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- DZIP1 | c.*3105C>T | 3'UTR (SNP) | VAF 20/63 reads (32%) | catalogued as rs371743954; called by muse, mutect2, varscan2
- ERMARD | c.1395-35T>A | Intron (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- GCSAML | c.*504A>G | 3'UTR (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- ITGA4 | c.*1607T>C | 3'UTR (SNP) | VAF 26/107 reads (24%) | catalogued as rs1167177481; called by muse, mutect2, varscan2
- KDELR2 | c.*1691T>A | 3'UTR (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- KIF5A | c.2992+88dup | Intron (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- KLHDC2 | c.883+100T>G | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, varscan2
- LINC02756 | n.311+16086G>T | Intron (SNP) | VAF 36/58 reads (62%) | called by muse, mutect2, varscan2
- MED8 | c.*1050C>T | 3'UTR (SNP) | VAF 14/50 reads (28%) | catalogued as rs555934381; called by muse, mutect2, varscan2
- MOGAT2 | c.*368G>C | 3'UTR (SNP) | VAF 52/165 reads (32%) | called by muse, mutect2, varscan2
- MOV10L1 | c.555+112C>T | Intron (SNP) | VAF 43/156 reads (28%) | called by muse, mutect2, varscan2
- NAA16 | c.2299+34T>C | Intron (SNP) | VAF 37/135 reads (27%) | catalogued as rs199608504; called by muse, mutect2, varscan2
- NKX6-3 | c.*1226T>G | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- ODF2L | c.113+219T>C | Intron (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- OFCC1 | n.314T>A | RNA (SNP) | VAF 93/279 reads (33%) | called by muse, mutect2, varscan2
- PIP4K2A | c.*1948T>C | 3'UTR (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- PKD2 | c.-25C>T | 5'UTR (SNP) | VAF 19/39 reads (49%) | catalogued as rs1288057838; called by muse, mutect2, varscan2
- POLR1F | c.*387A>G | 3'UTR (SNP) | VAF 124/248 reads (50%) | called by muse, mutect2, varscan2
- PPTC7 | c.*2444dup | 3'UTR (INS) | VAF 11/60 reads (18%) | catalogued as rs539542512; called by mutect2, varscan2
- PRRC1 | c.1129-1343A>G | Intron (SNP) | VAF 57/155 reads (37%) | called by muse, mutect2, varscan2
- PRRX1 | c.*1323C>A | 3'UTR (SNP) | VAF 24/94 reads (26%) | catalogued as COSV53411841; called by muse, mutect2, varscan2
- PRTG | c.*5010A>G | 3'UTR (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+578A>T | Intron (SNP) | VAF 95/196 reads (48%) | called by muse, mutect2, varscan2
- RAB42 | c.*958C>T | 3'UTR (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- RFX3 | c.1202+64A>T | Intron (SNP) | VAF 118/217 reads (54%) | called by muse, mutect2, varscan2
- SCFD1 | c.312+698G>A | Intron (SNP) | VAF 18/51 reads (35%) | catalogued as rs1485486461; called by muse, mutect2
- STPG2 | c.*1052T>G | 3'UTR (SNP) | VAF 103/186 reads (55%) | called by muse, mutect2, varscan2
- TAF8 | c.*4320A>G | 3'UTR (SNP) | VAF 6/28 reads (21%) | catalogued as rs1281917567; called by muse, mutect2
- TBX3 | c.*455T>C | 3'UTR (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- THAP9 | c.*981C>G | 3'UTR (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- TMEM169 | c.*1362T>C | 3'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- TOX2 | c.*532del | 3'UTR (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- TRAF3 | c.*2678C>T | 3'UTR (SNP) | VAF 92/146 reads (63%) | catalogued as rs1016412101; called by muse, mutect2, varscan2
- TRIM38 | c.*99T>G | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- TRIP11 | c.*1695A>G | 3'UTR (SNP) | VAF 41/174 reads (24%) | catalogued as rs1361551423; called by muse, mutect2, varscan2
- TYW1 | c.*207A>C | 3'UTR (SNP) | VAF 59/295 reads (20%) | called by muse, mutect2, varscan2
- WDR90 | c.3391+58C>T | Intron (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2
- ZBTB40 | c.*2298T>C | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- ZNF44 | c.*547C>G | 3'UTR (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- ZNF525 | c.*3675G>C | 3'UTR (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
